Somatic mutation profile of tumor specimen TCGA-E7-A8O7-01A (aliquot TCGA-E7-A8O7-01A-11D-A364-08) from TCGA case TCGA-E7-A8O7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 52.2 years (19,063 days).
Specimen TCGA-E7-A8O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eceffabd-a5c6-40bc-a7d8-d23995e69cb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A8O7-10A (Blood Derived Normal), aliquot TCGA-E7-A8O7-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30984fc5-f1ea-4f20-b753-1a885bb00d57

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 13, Nonsense Mutation 4, Frame Shift Del 2, Translation Start Site 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF12 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755000; called by muse, mutect2
- ARNT | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV100591250; called by muse, mutect2, varscan2
- CSMD3 | c.1597T>A p.F533I (on ENST00000297405 / NM_001363185.1; = p.F429I on NM_052900.3) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV52184542, COSV52258494; called by muse, mutect2, varscan2
- FAM98A | c.38C>A p.S13* | Nonsense Mutation (SNP) | VAF 69/156 reads (44%) | catalogued as COSV99479377; called by muse, mutect2, varscan2
- GRM8 | c.1198G>T p.G400* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs1354751327, COSV100283917, COSV100286617; called by muse, mutect2, varscan2
- HTR1A | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60500863; called by muse, mutect2, varscan2
- KDM6A | c.3657G>T p.W1219C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100938337, COSV65042442, COSV65048736; called by muse, mutect2
- KNTC1 | c.2878G>C p.V960L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV61080274; called by muse, mutect2, varscan2
- MRPL44 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs774482943, COSV51312869; called by muse, mutect2, varscan2
- NDUFS4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs377526472, COSV57018909; called by muse, mutect2
- OR1D2 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs746101467, COSV58921643; called by muse, mutect2
- RGPD2 | c.3832G>C p.D1278H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs759751747, COSV100553056, COSV100553112; called by mutect2, varscan2
- RRP9 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1254870023, COSV51754417; called by muse, mutect2, varscan2
- SLC6A7 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs1239391602, COSV57939101; called by muse, mutect2, varscan2
- SNRNP40 | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55277550; called by muse, mutect2, varscan2
- SNRPA | c.622C>G p.H208D | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV54681294; called by muse, mutect2, varscan2
- SPG7 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.598); catalogued as rs774691810, COSV51950630; called by muse, mutect2, varscan2
- TUT4 | c.3472G>C p.D1158H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57114206, COSV57117558; called by muse, mutect2, varscan2
- TXK | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV51915524; called by muse, mutect2, varscan2
- USP6 | c.3485C>T p.S1162L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV51482711; called by muse, mutect2, varscan2
- CIZ1 | c.495_517del p.G166Vfs*43 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel
- PAF1 | c.1383_1384insAAG p.E461_D462insK | In Frame Ins (INS) | VAF 50/116 reads (43%) | called by mutect2, pindel, varscan2
- SYT4 | c.650del p.P217Qfs*27 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- ADCK5 | c.411G>A p.G137= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV58233621; called by muse, mutect2, varscan2
- ATAD3A | c.1329C>G p.L443= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100186408; called by muse, mutect2, varscan2
- BCL2L12 | c.582C>T p.P194= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV55864141; called by muse, mutect2, varscan2
- CENPE | c.2277G>A p.L759= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs1475326820, COSV54379530; called by muse, mutect2, varscan2
- CNTNAP2 | c.811C>T p.L271= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV62183038; called by muse, mutect2
- DNAH10 | c.5739C>T p.L1913= (on ENST00000409039; = p.L1852= on NM_207437.3) | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV68994015; called by muse, mutect2, varscan2
- HCN1 | c.2301G>A p.V767= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV57511352; called by muse, mutect2, varscan2
- KIAA0513 | c.456G>A p.E152= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as COSV50741451; called by muse, mutect2, varscan2
- MCHR2 | c.405C>A p.L135= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV56003240, COSV99911774; called by muse, mutect2, varscan2
- NR2C1 | c.339C>T p.C113= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1258534936, COSV58009995; called by muse, mutect2, varscan2
- PBRM1 | c.441A>C p.T147= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV56276786; called by muse, mutect2, varscan2
- RYR2 | c.6753T>C p.N2251= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs753920249, COSV100771317; called by muse, varscan2
- ZAN | c.7413C>T p.Y2471= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV61807069; called by muse, mutect2
- AC074085.2 | n.129G>A | RNA (SNP) | VAF 41/89 reads (46%) | catalogued as rs932831910; called by muse, mutect2, varscan2
